Gene-level copy-number profile of tumor specimen TCGA-EQ-5647-01A from TCGA case TCGA-EQ-5647, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 86.1 years (31,431 days).
Specimen TCGA-EQ-5647-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.5b8efedf-1535-4ee4-a813-12e44d5d090f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EQ-5647-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/11b39c9f-0bcf-4d46-b774-3eea6bc0c651

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 935; copy number 2: 12,982; copy number 3: 23,982; copy number 4: 8,776; copy number 5: 7,258; copy number 6: 2,380; copy number 7: 2,716; copy number 8: 3; copy number 9: 116; copy number 10: 32; copy number 12: 7; copy number 13: 83; copy number 14: 33; copy number 15: 64; copy number 16: 12; copy number 18: 11; copy number 19: 9; copy number 20: 50; copy number 21: 21; copy number 22: 66; copy number 24: 24; copy number 25: 22; copy number 27: 75; copy number 31: 8; copy number 32: 43; copy number 33: 7; copy number 35: 65; copy number 43: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EQ-5647-01A-01D-1599-01): tumor purity 0.59, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,504 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,171,609–165,356,715, 193 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:166,763,334–169,630,193, 71 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:207,959,292–248,919,946, 881 genes, copy number 7 (broad region; genes not listed).
- chr2:10,717,773–17,123,140, 90 genes, copy number 9–15 (broad region; genes not listed).
- chr2:61,017,225–61,191,203, 7 genes, copy number 7: PEX13, KIAA1841, AC016747.4, AC016747.1, C2orf74, AC016747.2, AHSA2P.
- chr2:61,199,979–61,200,769, 1 gene, copy number 7: AC016747.3.
- chr3:70,751,123–79,767,998, 107 genes, copy number 10–32 (within-gene range 2–32) (broad region; genes not listed).
- chr3:160,755,602–198,222,513, 658 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr5:32,888,236–43,412,391, 184 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr5:152,374,998–155,199,252, 37 genes, copy number 7: AC008571.2, NMUR2, AC008571.1, LINC01470, GRIA1, RN7SL177P, LINC01861, AC091962.1, FAM114A2, MFAP3, GALNT10, SAP30L-AS1, HNRNPA3P7, AC008625.1, MIR1294, RN7SL655P, SAP30L, HAND1, AC026688.2, AC026688.1, CIR1P1, MIR3141, MIR1303, Y_RNA, LARP1, RN7SL803P, AC008379.1, FAXDC2, Metazoa_SRP, MIR378H, CNOT8, GEMIN5, MRPL22, AC008410.1, KIF4B, AC010476.2, AC010476.1.
- chr8:118,923,557–145,066,685, 481 genes, copy number 7 (broad region; genes not listed).
- chr10:44,259,602–46,131,358, 56 genes, copy number 7: AL137026.2, AL137026.1, LINC02881, AL137026.3, CXCL12, RPL9P21, AL356157.2, AL356157.3, AL356157.1, TMEM72-AS1, EIF2AP4, AL353801.2, TMEM72, AL353801.1, AL353801.3, RASSF4, DEPP1, ZNF22-AS1, ZNF22, CEP164P1, AL358394.3, DUXAP4, RPS19P7, RSU1P2, CUBNP3, AL358394.2, ANKRD54P1, ANKRD30BP3, MIR3156-1, AL358394.1, AL512324.3, AL512324.6, RNU6-1207P, CUBNP2, OR6D1P, OR13A1, ALOX5, AL731567.1, MARCHF8, ZFAND4, AGAP10P, FAM21FP, AL645998.1, WASHC2C, AC012044.1, FAM25E, AGAP4, PARGP1, RNA5SP310, RPL35AP23, TIMM23, SNORA74C-1, NCOA4, MSMB, RPL23AP61, AGAP7P.
- chr12:17,710,934–29,158,537, 177 genes, copy number 7–27 (broad region; genes not listed).
- chr12:29,156,448–29,156,991, 1 gene, copy number 7: AC012150.2.
- chr12:53,380,176–53,727,745, 19 genes, copy number 7: SP1, AMHR2, PRR13, AC023509.1, PCBP2, PCBP2-OT1, AC023509.4, MAP3K12, AC023509.3, TARBP2, ATF7-NPFF, NPFF, ATF7, AC023509.2, AC023509.6, AC023509.5, ATP5MC2, AC073594.1, CALCOCO1.
- chr12:55,900,300–56,117,967, 19 genes, copy number 14: GSTP1P1, PYM1, DGKA, AC025162.2, PMEL, CDK2, AC025162.1, RAB5B, AC034102.1, SUOX, IKZF4, AC034102.8, AC034102.3, RPS26, ERBB3, AC034102.2, PA2G4, AC034102.4, RPL41.
- chr12:56,118,260–56,129,619, 3 genes, copy number 14 (within-gene range 6–14): ZC3H10, AC034102.7, AC034102.6.
- chr12:56,271,699–56,317,992, 5 genes, copy number 7 (within-gene range 6–7): CS, AC073896.1, AC073896.2, AC073896.3, CNPY2.
- chr12:58,087,892–58,813,060, 7 genes, copy number 16 (within-gene range 5–16): LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388.
- chr12:59,129,511–59,130,875, 1 gene, copy number 7: AC046129.1.
- chr12:67,648,338–74,402,600, 115 genes, copy number 12–35 (within-gene range 3–35) (broad region; genes not listed).
- chr12:81,257,975–88,142,099, 51 genes, copy number 7–33 (within-gene range 3–33): PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1, AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.1, AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1, AC090679.3, AC090679.2, AC087888.1, AC093027.1, SLC6A15, AC128657.1, TSPAN19, LRRIQ1, ALX1, LINC02820, AC126471.1, AC137768.1, RASSF9, NTS, MGAT4C, AC016993.1, AC139697.1, AC010196.1, AC079597.1, RPL23AP68, AC079598.4, CYCSP30, AC079598.2, MKRN9P, LINC02258, AC079598.1, AC079598.3, RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1.
- chr12:99,985,045–104,177,799, 97 genes, copy number 9–13 (broad region; genes not listed).
- chr13:112,376,355–112,887,168, 8 genes, copy number 7: SPACA7, TUBGCP3, AL139384.2, ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1.
- chr18:21,914,369–23,026,488, 24 genes, copy number 20: AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.
- chr18:29,048,620–29,361,963, 3 genes, copy number 8: RNU6-408P, AC105245.1, AC074237.1.
- chr19:27,902,595–29,921,653, 45 genes, copy number 7 (within-gene range 3–7): AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58.
- chr19:29,956,369–29,956,988, 1 gene, copy number 7: RPL9P32.
- chr20:35,928,570–36,088,192, 8 genes, copy number 19: RNU6-937P, SCAND1, CNBD2, NORAD, AL035420.1, AL035420.3, HMGB3P2, AL035420.2.
- chr20:36,507,702–36,870,402, 13 genes, copy number 19–21 (within-gene range 17–21): DLGAP4-AS1, MYL9, Metazoa_SRP, TGIF2, TGIF2-RAB5IF, RAB5IF, SLA2, HNRNPA3P2, NDRG3, Y_RNA, DSN1, SOGA1, RN7SL156P.
- chr20:40,121,041–40,854,229, 5 genes, copy number 15–21: AL009050.1, MAFB, AL035665.1, AL035665.2, RNA5SP484.
- chr20:47,501,887–47,827,044, 5 genes, copy number 16 (within-gene range 3–16): NCOA3, AL034418.1, SULF2, AL354813.1, RNU7-173P.
- chr20:51,386,957–54,651,169, 45 genes, copy number 31–43 (within-gene range 3–43): NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5.
- chr20:55,607,852–59,007,254, 86 genes, copy number 10–32 (within-gene range 3–32) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 935. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
